Surgical pathology report (de-identified scan), TCGA case TCGA-LT-A5Z6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Gundersen Lutheran Health System, specimen TCGA-LT-A5Z6-01A (Primary Tumor).

Patient:

Med. Record. No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: M

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

ICD-O-3
Carcinoma, Urothelial (Transitional cell)
8120/3
Site Bladder, NOS 067.9

SPECIMEN

Urinary bladder, transurethral resection of tumor (TURB-T)
Muscularis propria present in specimen

TUMOR

Histologic type: Urothelial (transitional cell) carcinoma, with glandular differentiation

Histologic grade: High grade

Extent of invasion: Invasion of muscularis propria (detrusor muscle)

Venous/lymphatic invasion: Absent

Associated epithelial lesions: None identified

10% glandular
differentiation, per TSS.

STAGING (AJCC)

Primary Tumor: pT2

Lymph Nodes: pNX

Distant Metastasis: Cannot be assessed

CLINICAL INFORMATION:

Bladder tumor

SPECIMEN(S) RECEIVED:

Bladder tumor

GROSS DESCRIPTION:

Received in formalin and partially contained in two gauze sacs are multiple irregular fragments of moderately friable, tan pink to red-gray tissue weighing 6.9 grams in aggregate. specimen also collected in the operating suite. Tissue submitted in A1 - A8, wrapped.

Slides were microscopically examined by the pathologist.

Evaluation performed by

Electronically signed

Pathology Report

Source: NCI Genomic Data Commons file df7e0a7e-0b66-410b-a6b5-0abf9d84400e (TCGA-LT-A5Z6.1249D02D-48D2-477E-AAAE-51B1D625C8F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).